TCGA case TCGA-D3-A3BZ — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c3d4caa5-eebc-4276-b1e1-ab9494867b10

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 63 years; Vital status: Alive.

Diagnoses (4)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.0; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: Progression; Age at diagnosis: 65.1 years (23,774 days); Days to diagnosis: 488 days (1.3 years); Prior treatment: No; Days to last follow up: 3,976 days (10.9 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 63.8 years (23,286 days); Year of diagnosis: 2002; AJCC staging edition: 7th; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 551 days (1.5 years); Days to treatment end: 565 days (1.5 years); Treatment dose: 30 Gy; Number of fractions: 5; Treatment anatomic sites: Regional Site.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
3. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: V; Sites of involvement: Skin, Head and Neck; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
4. Basal cell carcinoma, NOS: ICD-O-3 morphology code: 8090/3; Tissue or organ of origin: Head, face or neck, NOS; Classification of tumor: Subsequent Primary; Age at diagnosis: 70.2 years (25,626 days); Days to diagnosis: 2,340 days (6.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 2,340 days (6.4 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 3,516 days (9.6 years); Disease response: Tumor Free.
- Days to follow up: 3,976 days (10.9 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 1.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 99 kg; Height: 170 cm; BMI: 34.3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D3-A3BZ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-D3-A3BZ-06A-01-TSA: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 75; Percent normal cells: 40; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.
- Sample TCGA-D3-A3BZ-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D3-A3BZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Breslow thickness at diagnosis: 4.6; Primary melanoma tumor ulceration: No; Primary melanoma mitotic rate: 1; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Head and Neck; Melanoma primary count: 1.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Subsequent known primaries: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,976 days; disease-specific survival: no event (censored), 3,976 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,340 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D3-A3BZ-06A-12D-A194-01): tumor purity 0.96, ploidy 2.03, whole-genome doublings 0.
